Somatic mutation profile of tumor specimen TCGA-V4-A9EU-01A (aliquot TCGA-V4-A9EU-01A-11D-A39W-08) from TCGA case TCGA-V4-A9EU, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Epithelioid cell melanoma; Tissue or organ of origin: Ciliary body; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 83.3 years (30,409 days).
Specimen TCGA-V4-A9EU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8243889-5975-4415-98e6-f97ed7ae7d85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9EU-10A (Blood Derived Normal), aliquot TCGA-V4-A9EU-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e73ac42c-f393-4649-9cde-5c3b0ffff557

The open-access MAF lists 10 somatic variants for this specimen: 10 protein-altering or splice-affecting.
By variant classification: Missense Mutation 8, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.1321C>T p.Q441* | Nonsense Mutation (SNP) | VAF 28/32 reads (88%) | catalogued as rs1559587104; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DDX51 | c.1674G>A p.L558= | Splice Region (SNP) | VAF 18/38 reads (47%) | catalogued as rs1243377122, COSV57959207; called by muse, mutect2, varscan2
- SLC12A5 | c.1433C>T p.A478V (on ENST00000454036 / NM_001134771.2; = p.A455V on NM_020708.5) | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs1340483692; called by muse, mutect2, varscan2
- TTLL4 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs761668602, COSV51437877; called by muse, mutect2, varscan2
- ARSB | c.634A>G p.T212A | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- FAM171A1 | c.760T>C p.W254R | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MACF1 | c.6595C>G p.P2199A | Missense Mutation (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
- NME7 | c.727A>G p.I243V | Missense Mutation (SNP) | VAF 91/196 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZDHHC23 | c.952G>C p.G318R | Missense Mutation (SNP) | VAF 37/41 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
